Somatic mutation profile of tumor specimen ALCH-ADU8-TTP1-A (aliquot ALCH-ADU8-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADU8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.2 years (20,910 days).
Specimen ALCH-ADU8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4df60d3c-5283-446d-93f8-d6be93b61711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADU8-NB1-A (Blood Derived Normal), aliquot ALCH-ADU8-NB1-A-2-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f0842c1-721d-45aa-9d79-40232d1e9dd6

The open-access MAF lists 147 somatic variants for this specimen: 104 protein-altering or splice-affecting, 26 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 26, Nonsense Mutation 11, Intron 6, 3'UTR 5, RNA 3, 5'UTR 1, Splice Region 1, 3'Flank 1, Splice Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJC6 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 14/318 reads (4%) | catalogued as rs886039854; ClinVar: pathogenic; called by muse, mutect2
- DSP | c.3348T>A p.Y1116* | Nonsense Mutation (SNP) | VAF 36/650 reads (6%) | catalogued as rs772646601; ClinVar: pathogenic; called by muse, mutect2
- MAP2K1 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 44/744 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs1057519729, COSV61068787; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA1 | c.3929G>T p.G1310V | Missense Mutation (SNP) | VAF 38/705 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV66066122; called by muse, mutect2
- APP | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1375631745; called by muse, mutect2
- ARHGEF6 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1168744786; called by muse, mutect2
- ASXL2 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs1374566661; called by muse, mutect2
- CNOT1 | c.1772G>T p.R591L | Missense Mutation (SNP) | VAF 21/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57764018; called by muse, mutect2
- CNTNAP2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as rs756180841, COSV100662536, COSV62150589; ClinVar: uncertain significance; called by muse, mutect2
- COL4A5 | c.3005C>A p.P1002Q | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV100086809, COSV100087200; called by muse, mutect2
- CTSK | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 34/654 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255952340; called by muse, mutect2
- EFCAB10 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); catalogued as rs1411757123; called by muse, mutect2
- FZD2 | c.1426G>C p.V476L | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV59528778; called by muse, mutect2
- IAPP | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs369714240, COSV99557193, COSV99557221; called by muse, mutect2
- ITK | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 33/549 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs774659403, COSV70062380; called by muse, mutect2
- KMT2A | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs892601475, COSV100630379; called by muse, mutect2
- LRRC73 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1272922204; called by muse, mutect2
- MAGI1 | c.3460G>C p.E1154Q (on ENST00000402939 / NM_001033057.2; = p.E1183Q on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV58325464; called by muse, mutect2
- MBNL3 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100898491; called by muse, mutect2
- MORF4L1 | c.235G>T p.G79* | Nonsense Mutation (SNP) | VAF 18/437 reads (4%) | catalogued as COSV100489189; called by muse, mutect2
- NUP160 | c.1343G>T p.R448I | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as COSV65856181; called by muse, mutect2
- OR1A2 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV67936879; called by muse, mutect2, varscan2
- OR2D2 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 22/393 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.698); catalogued as COSV100203856; called by muse, mutect2
- OR4D1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV52125189; called by muse, mutect2
- PCDH18 | c.1850G>T p.S617I | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61266328; called by muse, mutect2
- PLCG2 | c.1425C>A p.H475Q | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs925017425; called by muse, mutect2
- PSG9 | c.1214T>C p.I405T | Missense Mutation (SNP) | VAF 25/349 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.103); catalogued as rs902339210; called by muse, mutect2
- PTPRT | c.2695G>T p.G899W | Missense Mutation (SNP) | VAF 21/423 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61959474, COSV61974259; called by muse, mutect2
- SEMA3D | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 43/780 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99407346; called by muse, mutect2
- SLC35D1 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 46/740 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372640176; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99823395; called by muse, mutect2
- TSHZ3 | c.1436C>A p.A479E | Missense Mutation (SNP) | VAF 49/881 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53668205; called by muse, mutect2
- UGT1A7 | c.233C>A p.S78* | Nonsense Mutation (SNP) | VAF 35/341 reads (10%) | catalogued as COSV60850052; called by muse, mutect2, varscan2
- USP54 | c.964C>G p.H322D | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60446158; called by muse, mutect2
- XIRP2 | c.2123C>A p.P708Q (on ENST00000628543; = p.P883Q on NM_152381.6) | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99741849; called by muse, mutect2, varscan2
- ZFP57 | c.622T>C p.C208R | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs950226844; called by muse, mutect2
- ABCA1 | c.3928G>T p.G1310W | Missense Mutation (SNP) | VAF 38/708 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- ADGRL3 | c.2690C>A p.T897K (on ENST00000506720 / NM_001322402.2; = p.T829K on NM_015236.6) | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.491); called by muse, mutect2
- AMOT | c.2303G>T p.R768L (on ENST00000371959 / NM_001113490.1; = p.R359L on NM_133265.3) | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AP4B1 | c.1915A>G p.K639E | Missense Mutation (SNP) | VAF 21/381 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- APC2 | c.4864_4872del p.P1622_A1624del | In Frame Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ARRDC2 | c.694G>C p.A232P | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- BTK | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 34/933 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CA14 | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CASQ2 | c.795G>C p.L265F | Missense Mutation (SNP) | VAF 21/581 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.393); called by muse, mutect2
- CATSPERE | c.534G>T p.R178S | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- CCDC160 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.178); called by muse, mutect2
- CCT6A | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2
- CFAP53 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 44/688 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.231); called by muse, mutect2
- CNTLN | c.1978A>T p.R660* | Nonsense Mutation (SNP) | VAF 29/502 reads (6%) | called by muse, mutect2
- COL3A1 | c.4011G>A p.Q1337= | Splice Region (SNP) | VAF 12/364 reads (3%) | called by muse, mutect2
- CUL4B | c.2182G>T p.G728* | Nonsense Mutation (SNP) | VAF 40/871 reads (5%) | called by muse, mutect2
- CXCL14 | c.221G>A p.S74N (on ENST00000337225; = p.S62N on NM_004887.5) | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.023); called by muse, mutect2
- DCBLD2 | c.1709G>T p.W570L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2
- DHX36 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DLX2 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- DSTYK | c.1928T>C p.L643S | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- EPB42 | c.434A>G p.D145G (on ENST00000441366 / NM_001114134.2; = p.D175G on NM_000119.3) | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXO31 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- FGA | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 32/421 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); called by muse, mutect2
- FN1 | c.2908G>T p.G970W | Missense Mutation (SNP) | VAF 33/599 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABBR1 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- GABBR1 | c.1306C>A p.R436S | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRA1 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 55/792 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GABRE | c.1427A>T p.H476L | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- GATAD1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 23/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCSAML | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 21/399 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- GOLT1A | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HDAC9 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 19/520 reads (4%) | called by muse, mutect2
- HEPACAM2 | c.842C>A p.S281Y (on ENST00000394468 / NM_001039372.4; = p.S269Y on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- HEPH | c.638G>T p.G213V (on ENST00000343002; = p.G267V on NM_138737.5) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2
- IFIH1 | c.1139T>A p.F380Y | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IGHV2-5 | c.222G>C p.W74C | Missense Mutation (SNP) | VAF 30/698 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); called by muse, mutect2
- IGLV5-52 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2
- KIF4A | c.872C>A p.S291Y | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LGSN | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); called by muse, mutect2
- MAP3K21 | c.1296G>C p.L432F | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MMP20 | c.906T>G p.F302L | Missense Mutation (SNP) | VAF 56/982 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- MMRN1 | c.2872C>A p.L958I | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2
- MS4A3 | c.266C>A p.T89K | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- NECAB1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 31/418 reads (7%) | called by muse, mutect2
- NHSL2 | c.629C>G p.S210* (on ENST00000510661; = p.S576* on NM_001013627.2) | Nonsense Mutation (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- NLRP12 | c.2528G>T p.G843V | Missense Mutation (SNP) | VAF 44/655 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP43 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- OR10P1 | c.794C>A p.A265E | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- OR10R2 | c.872A>G p.D291G | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- OR2AJ1 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OTOF | c.894C>G p.N298K | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI4 | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 20/465 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2
- PAPPA | c.3458G>T p.S1153I | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PGBD5 | c.1151G>C p.R384T (on ENST00000525115; = p.R453T on NM_001258311.2) | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- PLS3 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2
- PRKCD | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 27/455 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RADX | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 51/770 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); called by muse, mutect2
- SETBP1 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 33/807 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SETBP1 | c.486+1G>T p.X162_splice | Splice Site (SNP) | VAF 32/806 reads (4%) | called by muse, mutect2
- SLITRK4 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.829); called by muse, mutect2
- STON1 | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- TIMM17A | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); called by muse, mutect2
- TOE1 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR87 | c.5509A>T p.K1837* | Nonsense Mutation (SNP) | VAF 22/353 reads (6%) | called by muse, mutect2
- ZHX3 | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 22/588 reads (4%) | called by muse, mutect2
- ZNF74 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- ZNF782 | c.437A>C p.Q146P | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CACNA1G | c.1134C>T p.L378= | Silent (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- DSG4 | c.1699C>T p.L567= | Silent (SNP) | VAF 22/519 reads (4%) | called by muse, mutect2
- DYRK2 | c.1326A>C p.S442= (on ENST00000344096 / NM_006482.3; = p.S369= on NM_003583.4) | Silent (SNP) | VAF 54/404 reads (13%) | called by muse, mutect2, varscan2
- EIF4G1 | c.2484C>T p.P828= (on ENST00000346169 / NM_198241.3; = p.P633= on NM_004953.5) | Silent (SNP) | VAF 44/766 reads (6%) | called by muse, mutect2
- FAM135B | c.2340G>A p.E780= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV52741556; called by muse, mutect2
- FLG | c.11409G>A p.Q3803= | Silent (SNP) | VAF 44/948 reads (5%) | catalogued as rs375547903; called by muse, mutect2
- FNIP1 | c.2790A>G p.E930= | Silent (SNP) | VAF 37/518 reads (7%) | called by muse, mutect2
- GAK | c.1002G>A p.Q334= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- GNAI1 | c.738C>T p.S246= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- IGHMBP2 | c.1452G>T p.T484= | Silent (SNP) | VAF 36/626 reads (6%) | called by muse, mutect2
- IRAK3 | c.267C>A p.V89= | Silent (SNP) | VAF 62/462 reads (13%) | called by muse, mutect2, varscan2
- KIF1A | c.1239C>G p.R413= | Silent (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- LRFN5 | c.1464C>A p.A488= | Silent (SNP) | VAF 34/502 reads (7%) | called by muse, mutect2
- MTMR4 | c.528C>G p.V176= | Silent (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- MXRA5 | c.7428G>T p.V2476= | Silent (SNP) | VAF 22/364 reads (6%) | called by muse, mutect2
- MYH4 | c.1053C>A p.A351= | Silent (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- NCOA2 | c.2124A>C p.A708= | Silent (SNP) | VAF 15/336 reads (4%) | called by muse, mutect2
- NOC2L | c.519G>C p.V173= | Silent (SNP) | VAF 14/341 reads (4%) | called by muse, mutect2
- OLA1 | c.87A>T p.G29= | Silent (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- POU4F1 | c.1134C>G p.P378= | Silent (SNP) | VAF 21/292 reads (7%) | catalogued as rs1185167424; called by muse, mutect2
- RPRML | c.213C>A p.A71= | Silent (SNP) | VAF 29/344 reads (8%) | called by muse, mutect2
- SDK2 | c.4605G>C p.L1535= | Silent (SNP) | VAF 23/298 reads (8%) | called by muse, mutect2
- SMOC1 | c.489C>A p.T163= | Silent (SNP) | VAF 48/852 reads (6%) | catalogued as COSV62764021; called by muse, mutect2
- SVEP1 | c.342C>T p.P114= | Silent (SNP) | VAF 14/247 reads (6%) | catalogued as rs1368833591; called by muse, mutect2
- TMEM248 | c.567G>T p.T189= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- TTLL7 | c.2493T>G p.T831= | Silent (SNP) | VAF 22/397 reads (6%) | called by muse, mutect2
- AC005863.1 | n.392G>A | RNA (SNP) | VAF 34/499 reads (7%) | called by muse, mutect2
- AGMAT | c.*11C>G | 3'UTR (SNP) | VAF 15/252 reads (6%) | called by muse, mutect2
- ARHGEF10 | c.754+78G>A | Intron (SNP) | VAF 40/617 reads (6%) | called by muse, mutect2
- ARL13B | c.*2230G>C | 3'UTR (SNP) | VAF 27/932 reads (3%) | called by muse, mutect2
- ARMCX4 | c.1038+3600G>T | Intron (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- COL4A6 | c.147+41610A>G | Intron (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- EIF2B5 | c.2130+40C>G | Intron (SNP) | VAF 37/594 reads (6%) | called by muse, mutect2
- FAM153CP | chr5:178055966 C>A | 3'Flank (SNP) | VAF 45/615 reads (7%) | called by muse, mutect2
- GGTLC2 | chr22:22643470 G>A | 5'Flank (SNP) | VAF 44/882 reads (5%) | called by muse, mutect2
- GPR61 | c.-260C>G | 5'UTR (SNP) | VAF 20/489 reads (4%) | called by muse, mutect2
- MEIS1 | c.*128C>A | 3'UTR (SNP) | VAF 19/319 reads (6%) | catalogued as rs531315301; called by muse, mutect2
- MYCN | c.*9C>T | 3'UTR (SNP) | VAF 18/633 reads (3%) | called by muse, mutect2
- OR56B3P | n.86G>A | RNA (SNP) | VAF 18/298 reads (6%) | catalogued as rs1296083251; called by muse, mutect2
- RBM19 | c.36+16G>A | Intron (SNP) | VAF 56/364 reads (15%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+11072G>C | Intron (SNP) | VAF 23/289 reads (8%) | called by muse, mutect2
- ZNF849P | n.569G>T | RNA (SNP) | VAF 36/487 reads (7%) | called by muse, mutect2
- ZWINT | c.*170A>T | 3'UTR (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
